Gene-level copy-number profile of tumor specimen TCGA-ZG-A9KY-01A from TCGA case TCGA-ZG-A9KY, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 73.9 years (27,000 days).
Specimen TCGA-ZG-A9KY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.e7805163-e116-4f32-bead-1db31ccac6d7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZG-A9KY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 828 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/44410ed1-2aff-4fb4-8b08-4d0e044bf8b2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 745; copy number 1: 18,216; copy number 2: 34,789; copy number 3: 3,750; copy number 4: 1,612; copy number 5: 357; copy number 6: 207; copy number 7: 119.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZG-A9KY-01A-11D-A41J-01): tumor purity 0.67, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 745 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:45,786,987–46,036,122, 1 gene (within-gene range 0–2): MAST2.
- chr1:46,040,140–51,798,427, 125 genes (within-gene range 0–1) (broad region; genes not listed).
- chr16:71,281,389–90,222,851, 508 genes (broad region; genes not listed).
- chr22:46,360,834–50,801,309, 111 genes (within-gene range 0–3) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 683 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:202,940,826–204,728,106, 64 genes, copy number 7 (broad region; genes not listed).
- chr1:207,401,691–207,969,329, 17 genes, copy number 6: AL391597.1, CR2, CR1, AL137789.1, CR1L, CD46P1, CDCA4P3, RNA5SP534, AL137789.2, CD46, CDCA4P4, MIR29B2CHG, MIR29C, MIR29B2, CD34, AL356275.1, LINC02767.
- chr3:3,700,814–4,467,273, 1 gene, copy number 5 (within-gene range 4–5): SUMF1.
- chr3:3,918,709–4,414,960, 5 genes, copy number 5: AC023480.1, PNPT1P1, AC023483.1, SETMAR, MRPS10P2.
- chr3:13,316,235–14,201,122, 19 genes, copy number 5: NUP210, AC027124.2, AC027124.1, HDAC11-AS1, HDAC11, FBLN2, LINC00620, WNT7A, VN1R20P, FGD5P1, TPRXL, AC090004.2, VN1R21P, CHCHD4, TMEM43, AC090004.1, XPC-AS1, XPC, LSM3.
- chr3:123,490,820–123,961,408, 7 genes, copy number 5: HACD2, MYLK-AS1, MYLK, MYLK-AS2, AC020634.2, AC020634.1, CCDC14.
- chr4:1,056,250–2,732,573, 50 genes, copy number 5–7 (within-gene range 3–7): RNF212, AC092535.3, AC092535.4, TMED11P, AC092535.1, AC092535.2, SPON2, AC092535.5, CTBP1-AS, CTBP1, CTBP1-DT, MAEA, UVSSA, AC078852.2, AC078852.1, NKX1-1, AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22, NELFA, MIR943, C4orf48, NAT8L, POLN, HAUS3, AL136360.1, AL136360.2, COX6B1P5, MXD4, MIR4800, ZFYVE28, AL158068.2, RN7SL589P, AL158068.1, CFAP99, RNF4, AL645924.1, AL645924.2, FAM193A, CR545473.1, Y_RNA.
- chr4:41,220,074–41,303,337, 3 genes, copy number 5: UCHL1-AS1, UCHL1, Y_RNA.
- chr6:139,271,362–139,667,284, 1 gene, copy number 5 (within-gene range 3–5): AL592429.2.
- chr6:139,435,636–139,661,513, 3 genes, copy number 5 (within-gene range 3–5): LINC01625, ATP5PBP6, AL390205.1.
- chr8:124,823,702–125,367,120, 12 genes, copy number 6 (within-gene range 2–6): LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1.
- chr8:127,072,694–127,257,630, 4 genes, copy number 6: CASC19, PRNCR1, AC020688.1, AC018714.2.
- chr9:111,631,386–111,839,934, 5 genes, copy number 5 (within-gene range 2–5): DNAJC25-GNG10, GNG10, SHOC1, AL354877.1, RNU6-1013P.
- chr9:115,252,538–116,012,965, 5 genes, copy number 5: AL355601.1, AL691420.1, U2, LINC00474, AL691426.1.
- chr9:124,451,425–125,143,528, 18 genes, copy number 5 (within-gene range 3–5): ADGRD2, NR5A1, AL354979.1, NR6A1, AL669818.1, RN7SL302P, MIR181A2HG, MIR181A2, MIR181B2, AL354928.1, OLFML2A, WDR38, RPL35, ARPC5L, GOLGA1, RNU4-82P, SCAI, FXNP2.
- chr11:66,842,835–67,906,350, 63 genes, copy number 6 (broad region; genes not listed).
- chr11:68,870,664–71,252,577, 61 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr16:2,009,926–3,039,133, 107 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr17:17,759,154–21,594,180, 225 genes, copy number 5 (broad region; genes not listed).
- chr17:72,021,851–72,220,948, 3 genes, copy number 5 (within-gene range 4–5): ROCR, LINC01152, AC007461.1.
- chr17:72,072,333–72,126,416, 2 genes, copy number 5: LINC02097, SOX9.
- chr18:5,895,745–6,415,237, 4 genes, copy number 5 (within-gene range 3–5): AP001021.3, L3MBTL4, AP001021.2, RNU5F-3P.
- chr22:19,520,572–19,633,574, 4 genes, copy number 6: AC000082.1, CLDN5, LINC00895, AC000077.1.

Autosomal genes at a single copy (total copy number 1): 16,064. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
